Somatic mutation profile of tumor specimen TCGA-55-6987-01A (aliquot TCGA-55-6987-01A-11D-1945-08) from TCGA case TCGA-55-6987, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 77.7 years (28,382 days).
Specimen TCGA-55-6987-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d9e5bdf-3ea1-4e25-b7cd-bf799b4394b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-6987-11A (Solid Tissue Normal), aliquot TCGA-55-6987-11A-01D-1945-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1db85df-3a19-415e-a683-113cf66f5e1c

The open-access MAF lists 186 somatic variants for this specimen: 144 protein-altering or splice-affecting, 40 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 123, Silent 40, Nonsense Mutation 16, Frame Shift Del 3, Splice Region 1, Splice Site 1, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB8 | c.988G>T p.A330S (on ENST00000297504 / NM_001282291.2; = p.A313S on NM_007188.5) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.401); catalogued as COSV99874564; called by mutect2, varscan2
- ACP4 | c.1042C>G p.L348V | Missense Mutation (SNP) | VAF 23/213 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.056); catalogued as COSV54516596; called by muse, mutect2, varscan2
- ADCY5 | c.3203A>G p.E1068G | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV59196165; called by muse, mutect2
- ANXA6 | c.1280G>A p.R427K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV62906123; called by muse, mutect2
- APOBEC3A | c.44C>A p.P15Q | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.302); catalogued as COSV50779245; called by muse, mutect2, varscan2
- ATP1A2 | c.1990G>T p.G664C | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63402010, COSV63403080; called by muse, mutect2, varscan2
- BRMS1L | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as COSV53762228, COSV53762754; called by muse, mutect2, varscan2
- BRWD3 | c.1754C>G p.P585R | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64745948; called by muse, mutect2, varscan2
- CADPS | c.1691C>T p.A564V | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as rs898296147, COSV51871719; called by muse, mutect2
- CADPS2 | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57356335; called by muse, mutect2
- CDH12 | c.1832G>A p.G611E | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101201360, COSV66395997; called by mutect2, varscan2
- CENPF | c.2177C>G p.S726C | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV65273752; called by muse, mutect2, varscan2
- CLEC16A | c.2195A>C p.Y732S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.994); catalogued as COSV55489213; called by muse, mutect2, varscan2
- CLK2 | c.637G>C p.E213Q (on ENST00000368361 / NM_001294339.2; = p.E212Q on NM_003993.4) | Missense Mutation (SNP) | VAF 12/171 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.247); catalogued as COSV62876808; called by muse, mutect2
- CLK2 | c.430G>C p.E144Q (on ENST00000368361 / NM_001294339.2; = p.E143Q on NM_003993.4) | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV62876816; called by mutect2, varscan2
- COL11A1 | c.4828C>A p.L1610M | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62178044; called by muse, mutect2
- COL3A1 | c.1815G>A p.Q605= | Splice Region (SNP) | VAF 11/76 reads (14%) | catalogued as COSV58585027; called by muse, mutect2, varscan2
- CPA2 | c.919A>T p.S307C | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55979112; called by muse, mutect2, varscan2
- CUX2 | c.3401G>T p.R1134L | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.35); catalogued as COSV55628119; called by muse, mutect2, varscan2
- CXCL14 | c.163G>C p.E55Q (on ENST00000337225; = p.E43Q on NM_004887.5) | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61499174; called by muse, mutect2
- DACH2 | c.634C>A p.P212T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV64161713, COSV64165230; called by mutect2, varscan2
- DBX2 | c.877G>T p.E293* | Nonsense Mutation (SNP) | VAF 11/96 reads (11%) | catalogued as COSV60337009, COSV60337817; called by muse, mutect2, varscan2
- DDX21 | c.2053G>T p.V685L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.047); catalogued as COSV62555473; called by mutect2, varscan2
- DKC1 | c.762G>C p.M254I | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV65777247; called by muse, mutect2, varscan2
- DMXL2 | c.889C>T p.H297Y | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.036); catalogued as COSV51843113; called by muse, mutect2, varscan2
- DNAH9 | c.11697G>A p.M3899I | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52343009; called by muse, mutect2, varscan2
- DNMT3A | c.2341G>C p.D781H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53045830; called by muse, mutect2, varscan2
- DPY19L2 | c.618C>A p.F206L | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV60542522; called by muse, mutect2, varscan2
- DSCAM | c.2887A>G p.K963E | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (1); PolyPhen probably damaging (0.995); catalogued as COSV68023968; called by muse, mutect2
- DSP | c.1938C>A p.C646* | Nonsense Mutation (SNP) | VAF 15/112 reads (13%) | catalogued as COSV65792101; called by muse, mutect2, varscan2
- EIF3A | c.3634G>T p.D1212Y | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.424); catalogued as COSV64960874; called by muse, mutect2
- EIF3L | c.1570G>C p.D524H | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101094579, COSV67740245; called by muse, mutect2, varscan2
- EIF5A | c.447C>G p.I149M | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.137); catalogued as COSV59748288; called by muse, mutect2
- ELFN2 | c.1672G>T p.D558Y | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV68744225; called by muse, mutect2, varscan2
- ENPEP | c.2542C>G p.Q848E | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54448800; called by muse, mutect2
- EPG5 | c.1880G>T p.G627V | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56347386; called by muse, mutect2, varscan2
- EPHA7 | c.1401G>T p.E467D | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV65180210; called by muse, mutect2, varscan2
- EPHB3 | c.1210G>T p.G404C | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57805116, COSV57808500; called by muse, mutect2, varscan2
- EYS | c.1521C>A p.C507* | Nonsense Mutation (SNP) | VAF 12/56 reads (21%) | catalogued as COSV60981139; called by muse, mutect2, varscan2
- F11R | c.22G>C p.E8Q | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.084); catalogued as COSV57036751; called by muse, mutect2, varscan2
- FAF2 | c.223G>C p.D75H | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as COSV56130402; called by muse, mutect2, varscan2
- FAM71B | c.133C>G p.P45A | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57228278; called by muse, mutect2
- FAM71D | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV61295088; called by muse, mutect2
- FMNL1 | c.474G>C p.Q158H | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.212); catalogued as COSV58956044; called by muse, mutect2
- FOLH1 | c.1657C>G p.H553D | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57047456; called by muse, mutect2, varscan2
- FREM1 | c.5989G>A p.D1997N | Missense Mutation (SNP) | VAF 19/190 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV66521002; called by muse, mutect2
- FREM1 | c.2962C>A p.P988T | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV66521014; called by muse, mutect2, varscan2
- FRYL | c.8844A>C p.L2948F | Missense Mutation (SNP) | VAF 4/88 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV51943776; called by muse, mutect2
- FUT10 | c.610A>T p.K204* | Nonsense Mutation (SNP) | VAF 10/137 reads (7%) | catalogued as COSV59450613; called by muse, mutect2
- GAA | c.1650del p.T551Pfs*27 | Frame Shift Del (DEL) | VAF 9/58 reads (16%) | catalogued as CM040060, CM064002; called by mutect2, pindel
- GALNT2 | c.1345G>A p.A449T | Missense Mutation (SNP) | VAF 17/218 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.079); catalogued as rs1169786024, COSV64194051; called by muse, mutect2
- GCNA | c.460G>C p.D154H | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV65466296; called by mutect2, varscan2
- GEMIN8 | c.670G>T p.D224Y | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV60550288, COSV60551425; called by muse, mutect2, varscan2
- GJB4 | c.619T>C p.Y207H | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58355824; called by muse, mutect2
- GPATCH1 | c.865G>C p.G289R | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50124476, COSV99404114; called by muse, mutect2, varscan2
- GPATCH1 | c.866G>T p.G289V | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99404120; called by muse, varscan2
- HSPB8 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.84); PolyPhen benign (0.017); catalogued as rs757293016, COSV56136872, COSV56137127, COSV56137340; called by mutect2, varscan2
- IQCC | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.056); catalogued as rs1438069128, COSV52208156; called by muse, mutect2
- JMY | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.73); catalogued as COSV68660284; called by mutect2, varscan2
- KCNG3 | c.740G>C p.C247S | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV60148654; called by muse, mutect2
- KEAP1 | c.346C>T p.R116W | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV50270031; called by mutect2, varscan2
- KIF1B | c.2217G>T p.W739C (on ENST00000377086 / NM_001365952.1; = p.W693C on NM_015074.3) | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55806115; called by muse, mutect2
- KRT28 | c.334G>T p.A112S | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.084); catalogued as COSV60684637; called by muse, mutect2
- LBX1 | c.331G>C p.D111H | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV64621597; called by muse, mutect2, varscan2
- LRP2 | c.4294G>T p.A1432S | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0.113); catalogued as COSV55547407; called by muse, mutect2, varscan2
- LSAMP | c.514+2T>A p.X172_splice | Splice Site (SNP) | VAF 7/33 reads (21%) | catalogued as COSV61283485; called by muse, mutect2, varscan2
- MACF1 | c.21278A>G p.Y7093C (on ENST00000372915; = p.Y5138C on NM_012090.5) | Missense Mutation (SNP) | VAF 39/138 reads (28%) | catalogued as COSV57114332; called by muse, mutect2, varscan2
- MAGEE2 | c.637C>T p.Q213* | Nonsense Mutation (SNP) | VAF 9/45 reads (20%) | catalogued as COSV64897519; called by muse, mutect2, varscan2
- MINDY1 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.087); catalogued as rs1040245529, COSV56498117; called by muse, mutect2, varscan2
- MNDA | c.1117C>T p.Q373* | Nonsense Mutation (SNP) | VAF 30/109 reads (28%) | catalogued as rs748230240, COSV63740373; called by muse, varscan2
- MYT1L | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 13/162 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV67715120; called by muse, mutect2
- NAV3 | c.1468C>T p.Q490* | Nonsense Mutation (SNP) | VAF 7/71 reads (10%) | catalogued as COSV57071146; called by muse, mutect2
- NDST4 | c.1409T>A p.V470D | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52114040; called by muse, mutect2, varscan2
- NEK9 | c.2491C>G p.L831V | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as COSV53130084, COSV53133832; called by muse, mutect2, varscan2
- OR1A2 | c.784C>A p.L262M | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.389); catalogued as COSV101126346, COSV67936273; called by muse, mutect2, varscan2
- OR2L13 | c.920T>C p.F307S | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.174); catalogued as COSV63550708; called by muse, mutect2
- OR2T2 | c.509G>T p.C170F | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1194820225, COSV100737705; called by mutect2, varscan2
- OR4C15 | c.944C>A p.P315Q (on ENST00000314644; = p.P261Q on NM_001001920.2) | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.972); catalogued as COSV58951924, COSV58952417; called by muse, mutect2
- OR52B4 | c.512G>A p.C171Y | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760653620; called by mutect2, varscan2
- OR52R1 | c.717A>C p.K239N | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61887961; called by muse, mutect2
- OR5J2 | c.272C>G p.T91R | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as COSV56620586, COSV56622010; called by muse, mutect2
- OR5L1 | c.34T>G p.F12V | Missense Mutation (SNP) | VAF 14/237 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61733267; called by muse, mutect2
- OR6K2 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV62743299; called by muse, mutect2, varscan2
- OR6K3 | c.629T>A p.M210K (on ENST00000368146; = p.M194K on NM_001005327.2) | Missense Mutation (SNP) | VAF 17/186 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.21); catalogued as COSV63745495; called by muse, mutect2
- OR8H1 | c.567G>T p.M189I | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV57294375; called by muse, mutect2, varscan2
- PARVG | c.985G>T p.A329S | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as COSV63561607; called by muse, mutect2, varscan2
- PCDHA5 | c.574G>T p.E192* | Nonsense Mutation (SNP) | VAF 9/57 reads (16%) | catalogued as COSV65350840; called by muse, mutect2, varscan2
- PCDHA9 | c.2252C>A p.S751* | Nonsense Mutation (SNP) | VAF 12/89 reads (13%) | catalogued as COSV65324882; called by muse, varscan2
- PDE10A | c.2336C>T p.S779F | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.174); catalogued as COSV100604828, COSV63093987; called by muse, mutect2, varscan2
- PEG3 | c.242C>A p.T81N | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV55629524, COSV55633236; called by mutect2, varscan2
- PHACTR4 | c.1293G>A p.M431I (on ENST00000373839 / NM_001350159.2; = p.M441I on NM_023923.4) | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV65783540; called by muse, mutect2, varscan2
- POLR2J | c.40G>C p.E14Q | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as COSV52999832; called by muse, mutect2
- POP5 | c.118G>C p.V40L | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV58044272; called by muse, mutect2
- PRKDC | c.7958G>C p.R2653T | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as COSV58047987; called by muse, mutect2
- RASGEF1C | c.155C>A p.P52H | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV63179380; called by muse, varscan2
- RBM41 | c.1175C>G p.S392* | Nonsense Mutation (SNP) | VAF 19/132 reads (14%) | catalogued as COSV52562706; called by muse, mutect2, varscan2
- RIMS2 | c.3884G>T p.S1295I | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as rs1566691861, COSV51667841; called by muse, mutect2, varscan2
- RP1 | c.1274G>T p.W425L | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.212); catalogued as COSV55113678; called by muse, mutect2, varscan2
- RPL7L1 | c.264G>T p.L88F | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0.315); catalogued as COSV59034462; called by mutect2, varscan2
- RRAGB | c.357G>C p.L119F (on ENST00000262850 / NM_016656.4; = p.L91F on NM_006064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV53329004; called by muse, mutect2, varscan2
- RRP12 | c.1170G>T p.W390C | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59666356; called by muse, mutect2, varscan2
- RRP15 | c.781G>T p.D261Y | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65117627; called by muse, mutect2
- SEMA5A | c.310T>G p.C104G | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101228474; called by muse, mutect2
- SLA | c.725A>T p.E242V (on ENST00000338087 / NM_001045556.3; = p.E282V on NM_006748.4) | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV55070818; called by muse, mutect2, varscan2
- SLC18A2 | c.160G>C p.E54Q | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.023); catalogued as COSV53689447, COSV53692914; called by muse, mutect2
- SLC18B1 | c.1099G>C p.E367Q | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.262); catalogued as COSV51593847; called by muse, mutect2
- SLC35B4 | c.556A>T p.K186* | Nonsense Mutation (SNP) | VAF 18/100 reads (18%) | catalogued as COSV65984598; called by muse, mutect2, varscan2
- SLC39A1 | c.770G>A p.G257D | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57841800; called by muse, mutect2, varscan2
- SLC51B | c.301C>A p.P101T | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.571); catalogued as COSV54981150, COSV54981387; called by muse, mutect2, varscan2
- SLCO4A1 | c.1566C>A p.D522E | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.203); catalogued as rs759260457, COSV53889989; called by muse, mutect2, varscan2
- SMTN | c.203C>G p.S68C | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV60776731; called by muse, mutect2, varscan2
- SNX5 | c.335G>A p.G112D | Missense Mutation (SNP) | VAF 10/153 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as COSV66697718; called by muse, mutect2
- SOWAHA | c.544G>C p.A182P | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV66332389; called by muse, mutect2
- SV2A | c.140C>G p.S47C | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.619); catalogued as rs1394633706, COSV64964481; called by muse, mutect2, varscan2
- TAF1C | c.2183G>A p.R728Q | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.011); catalogued as rs1328428260, COSV58985569, COSV58985961; called by muse, mutect2, varscan2
- TECTB | c.904C>T p.R302W | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs374612200; called by muse, mutect2, varscan2
- TEF | c.337A>G p.S113G | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.23); catalogued as COSV56747520; called by muse, mutect2, varscan2
- TLK1 | c.1624G>C p.E542Q | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.917); catalogued as COSV62629643; called by muse, mutect2, varscan2
- TLR4 | c.138C>G p.Y46* (on ENST00000355622 / NM_138554.5; = p.Y6* on NM_003266.4) | Nonsense Mutation (SNP) | VAF 7/102 reads (7%) | catalogued as COSV62922806; called by muse, mutect2
- TMPRSS11E | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 26/242 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV59518523, COSV59518582; called by muse, varscan2
- TNN | c.3890G>A p.R1297Q | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as rs758620541, COSV53423901; called by muse, mutect2, varscan2
- TRPC5 | c.118G>T p.V40L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV53287122; called by muse, mutect2, varscan2
- TRRAP | c.11228G>T p.G3743V (on ENST00000359863 / NM_001244580.1; = p.G3714V on NM_003496.3) | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100705436, COSV62816229; called by mutect2, varscan2
- TSC22D4 | c.737T>A p.L246* | Nonsense Mutation (SNP) | VAF 17/97 reads (18%) | catalogued as COSV55723723; called by muse, mutect2, varscan2
- TULP4 | c.2775G>T p.L925F | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV65573939; called by muse, mutect2, varscan2
- UGT2B11 | c.955G>T p.E319* | Nonsense Mutation (SNP) | VAF 15/192 reads (8%) | catalogued as COSV71423193, COSV71423301; called by muse, mutect2
- UNC13C | c.1833G>C p.Q611H | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.121); catalogued as COSV52857096, COSV99517550; called by muse, mutect2, varscan2
- UNC79 | c.3638G>T p.R1213I (on ENST00000393151 / NM_001346218.2; = p.R1036I on NM_020818.5) | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56381080; called by muse, mutect2, varscan2
- UPK1A | c.156G>A p.M52I | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV55877836; called by muse, mutect2, varscan2
- USP26 | c.2092C>T p.R698* | Nonsense Mutation (SNP) | VAF 8/68 reads (12%) | catalogued as rs887422621, COSV63708329; called by muse, mutect2
- USP29 | c.1396C>A p.P466T | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV54142908, COSV99518228; called by muse, mutect2, varscan2
- USP29 | c.1397C>A p.P466H | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54141082, COSV54146187; called by muse, mutect2, varscan2
- VMA21 | c.285G>T p.W95C | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as COSV57756061, COSV57756219; called by muse, mutect2, varscan2
- VWF | c.4735G>T p.G1579W | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM011512, COSV54615661; called by muse, varscan2
- ZAN | c.3851C>A p.S1284Y | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV61807217; called by muse, mutect2, varscan2
- ZHX3 | c.1105G>C p.E369Q | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58382020, COSV58382170; called by mutect2, varscan2
- ZKSCAN2 | c.46G>C p.E16Q | Missense Mutation (SNP) | VAF 8/125 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.149); catalogued as COSV60156149; called by muse, mutect2
- ZNF157 | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as COSV65658678; called by muse, mutect2, varscan2
- ZNF536 | c.1424G>A p.S475N | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.046); catalogued as COSV62821564, COSV62837703; called by muse, mutect2
- ZNF614 | c.1186G>C p.E396Q | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54545690, COSV99571884; called by muse, mutect2, varscan2
- ZNF710 | c.983G>T p.C328F | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51562299; called by muse, mutect2, varscan2
- KCNF1 | c.1212del p.I405Sfs*25 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- PSG6 | c.132del p.V45Ffs*28 | Frame Shift Del (DEL) | VAF 22/190 reads (12%) | called by pindel, varscan2
- TRAV8-3 | c.242G>T p.G81V | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ABCA12 | c.5559C>G p.V1853= (on ENST00000272895 / NM_173076.3; = p.V1535= on NM_015657.3) | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV55953941; called by muse, mutect2, varscan2
- ADGRL4 | c.330T>C p.N110= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV100876127; called by muse, mutect2, varscan2
- ARHGAP36 | c.1221C>T p.H407= | Silent (SNP) | VAF 32/142 reads (23%) | catalogued as COSV52265251; called by muse, mutect2, varscan2
- BMERB1 | c.339G>A p.E113= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs750463940, COSV55507141; called by muse, mutect2, varscan2
- BTBD7 | c.1134G>C p.L378= | Silent (SNP) | VAF 3/45 reads (7%) | catalogued as COSV54134819, COSV54136295; called by muse, mutect2
- BTNL3 | c.870G>C p.V290= | Silent (SNP) | VAF 14/116 reads (12%) | catalogued as COSV61564694; called by muse, mutect2, varscan2
- CHST6 | c.774C>G p.L258= | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as rs966379903, COSV59999817; called by muse, mutect2
- DISP1 | c.3945G>A p.L1315= | Silent (SNP) | VAF 21/108 reads (19%) | catalogued as COSV52656972; called by muse, mutect2, varscan2
- DNAH9 | c.3750T>C p.D1250= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV52342995; called by mutect2, varscan2
- EPB41L4B | c.2211C>A p.S737= | Silent (SNP) | VAF 11/110 reads (10%) | catalogued as rs1161713949, COSV63124127; called by muse, mutect2, varscan2
- FAM214B | c.453C>T p.S151= | Silent (SNP) | VAF 7/74 reads (9%) | catalogued as COSV59715480; called by muse, mutect2
- FOXB1 | c.591C>T p.A197= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV68525745; called by muse, mutect2
- GRM7 | c.1863C>T p.V621= | Silent (SNP) | VAF 23/122 reads (19%) | catalogued as COSV63136966; called by muse, mutect2, varscan2
- HAS2 | c.1176C>G p.A392= | Silent (SNP) | VAF 13/116 reads (11%) | catalogued as COSV58262903; called by mutect2, varscan2
- HEATR1 | c.2862G>C p.L954= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as COSV63980298; called by muse, mutect2, varscan2
- IGSF6 | c.78C>A p.G26= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as rs766260469, COSV51678653, COSV99193648; called by muse, mutect2, varscan2
- KNTC1 | c.4872G>A p.S1624= | Silent (SNP) | VAF 11/105 reads (10%) | catalogued as rs1223166842, COSV61079447; called by muse, mutect2, varscan2
- LETMD1 | c.999C>T p.S333= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV50397019; called by muse, mutect2, varscan2
- MAGEA4 | c.939G>A p.E313= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV52340823; called by muse, mutect2, varscan2
- MAGI2 | c.2850G>T p.V950= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV62643589; called by muse, mutect2, varscan2
- MUC16 | c.34176A>T p.P11392= | Silent (SNP) | VAF 22/142 reads (15%) | catalogued as COSV67456013; called by muse, mutect2, varscan2
- MX1 | c.1806C>T p.F602= | Silent (SNP) | VAF 14/222 reads (6%) | catalogued as COSV55818500, COSV99912430; called by muse, mutect2
- NCF4 | c.585T>C p.D195= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as COSV50620918, COSV99957312; called by muse, mutect2, varscan2
- OR10R2 | c.858T>C p.Y286= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV63768664; called by muse, mutect2, varscan2
- OR56A1 | c.573C>T p.S191= | Silent (SNP) | VAF 7/74 reads (9%) | catalogued as COSV57362200; called by muse, mutect2
- OR5T1 | c.900C>T p.I300= | Silent (SNP) | VAF 9/93 reads (10%) | catalogued as COSV57302182; called by muse, mutect2
- PABPC4 | c.633C>T p.F211= | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as rs777812340, COSV63293317; called by muse, mutect2, varscan2
- PFKL | c.1056G>A p.V352= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV62463089; called by muse, mutect2, varscan2
- PIGO | c.390C>T p.T130= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as rs139962374, COSV53053022; called by muse, mutect2, varscan2
- PRAMEF14 | c.1362C>A p.P454= | Silent (SNP) | VAF 10/154 reads (6%) | called by muse, mutect2
- RYR1 | c.10857G>T p.V3619= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV62093461; called by muse, mutect2
- SEMA5A | c.309C>A p.A103= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as COSV101228475; called by muse, mutect2
- TCF25 | c.1230G>C p.R410= | Silent (SNP) | VAF 7/69 reads (10%) | catalogued as rs1358310749, COSV54525894; called by muse, mutect2, varscan2
- TFDP3 | c.378G>T p.G126= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs746809412, COSV59536424; called by muse, varscan2
- TRAV9-1 | c.273T>C p.S91= | Silent (SNP) | VAF 6/42 reads (14%) | called by mutect2, varscan2
- TRPM1 | c.1431G>A p.V477= | Silent (SNP) | VAF 17/105 reads (16%) | catalogued as rs760314625, COSV56632764; called by muse, mutect2, varscan2
- VWA3B | c.3039G>A p.P1013= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as rs374151826; called by muse, mutect2, varscan2
- XXYLT1 | c.945G>T p.V315= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV59982596; called by muse, mutect2, varscan2
- ZHX3 | c.1527G>C p.L509= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV58382157; called by muse, mutect2, varscan2
- ZNF407 | c.978G>T p.T326= | Silent (SNP) | VAF 23/137 reads (17%) | catalogued as COSV55247837; called by muse, mutect2, varscan2
- CALCR | c.52-3306C>T | Intron (SNP) | VAF 10/155 reads (6%) | catalogued as rs1269175184, COSV100810505; called by muse, mutect2
- FAM153CP | chr5:178055728 G>A | 3'Flank (SNP) | VAF 10/83 reads (12%) | catalogued as rs762030415; called by muse, mutect2, varscan2
